Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A5KH, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A5KH-06A (Metastatic).

Gross Description: A left inguinal lymph node is gray-black in cutting section, 4x3x2cm in size.

Microscopic Description: Lymph node architectures are replaced by tumor cells. Tumor is composed of spindle or oval tumor cells with quite scant cytoplasm. Tumor cells have a quite low nucleocytoplasmic ratio. Nucleus varies in shape and size with large esinophilic nucleoli. Mitotic figures are common. Tumor is necrotic. Lymphocytoid tissue are seen.

Diagnosis Details: Metastatic neoplasm, malignant melanoma

Comments:

Formatted Path Reports: Lymph node checklist

Specimen type: Metastatic neoplasm, malignant melanoma

Tumor location: Lymph node, inguinal, left, big toe

Surgical procedure: Surgical resection

Diagnosis details: None

Comments: None

ICD-O-3 8720/2
Malignant Melanoma NOS -
Site: Lymph node, inguinal
CT. 4
JED 2/1/13

primary melanoma from non-glabrous
area of toe - per TSS on 1/30/13.

HPV/A Discrepancy		☒

Source: NCI Genomic Data Commons file 6ec70510-5022-415c-8ae8-274ac1103f28 (TCGA-EB-A5KH.D02E858C-F41F-403C-BA85-D507FE5D125C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).